Somatic mutation profile of tumor specimen 0DUHI9 from CCDI case PBCLJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.6 years (2,043 days).
Specimen 0DUHI9: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64827767-0717-4a3d-a8d2-d49ed17e5c34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHGG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3cb4ec8-3d91-482c-b7e2-98f51a0a2f95

The open-access MAF lists 64 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 11, 3'UTR 4, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP44 | c.2197C>G p.R733G | Missense Mutation (SNP) | VAF 182/476 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as rs377074868, COSV99309872; called by muse, mutect2, varscan2
- CASKIN1 | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 149/365 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs947409656, COSV58213870; called by muse, mutect2, varscan2
- CFAP221 | c.1591A>G p.K531E | Missense Mutation (SNP) | VAF 158/579 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1332894832; called by muse, mutect2, varscan2
- CHST1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 99/637 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1261684073, COSV57322526; called by muse, mutect2, varscan2
- CYP2C19 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 270/646 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs202170044; called by muse, mutect2, varscan2
- GAS7 | c.1330G>A p.V444M (on ENST00000432992 / NM_201433.2; = p.V304M on NM_003644.3) | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1487812028; called by muse, mutect2, varscan2
- OR6K6 | c.990G>T p.R330S (on ENST00000368144; = p.R306S on NM_001005184.1) | Missense Mutation (SNP) | VAF 87/514 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV63744473; called by muse, mutect2, varscan2
- PRSS48 | c.131_132insGTCAC p.S44Rfs*21 | Frame Shift Ins (INS) | VAF 94/302 reads (31%) | catalogued as COSV71613542, COSV71613925; called by mutect2, pindel, varscan2
- RET | c.691C>A p.R231S | Missense Mutation (SNP) | VAF 25/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60699207; called by muse, mutect2
- SHANK3 | c.3532C>G p.R1178G | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs766500450; called by muse, mutect2, varscan2
- TTN | c.83302C>G p.R27768G (on ENST00000591111; = p.R20344G on NM_003319.4) | Missense Mutation (SNP) | VAF 132/460 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV59952095; called by muse, mutect2, varscan2
- ZFHX4 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 266/965 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.181); catalogued as rs909339083; called by muse, mutect2, varscan2
- AFM | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ATN1 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2
- BTBD11 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 70/222 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C4orf45 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CFAP57 | c.2537A>C p.Q846P | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HPS5 | c.2717+2T>A p.X906_splice (on ENST00000349215 / NM_181507.2; = p.X792_splice on NM_007216.4) | Splice Site (SNP) | VAF 118/538 reads (22%) | called by muse, mutect2, varscan2
- IFTAP | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 16/561 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- MAML3 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 154/419 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD14A | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSUN7 | c.1718A>G p.E573G | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2
- NUCB2 | c.659T>G p.V220G | Missense Mutation (SNP) | VAF 86/574 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OGT | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 96/124 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PCDHGB1 | c.2093T>C p.L698P | Missense Mutation (SNP) | VAF 147/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCGF6 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PDE4DIP | c.5173G>T p.G1725C | Missense Mutation (SNP) | VAF 133/567 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIK3CA | c.1259_1264del p.C420_P421del | In Frame Del (DEL) | VAF 71/393 reads (18%) | called by mutect2, pindel, varscan2
- PLCD3 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL10L | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 132/432 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TAS2R5 | c.272C>G p.A91G | Missense Mutation (SNP) | VAF 134/434 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TEX13C | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 138/181 reads (76%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR70 | c.328T>A p.S110T | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DUSP6 | c.612T>G p.P204= | Silent (SNP) | VAF 87/372 reads (23%) | called by muse, mutect2, varscan2
- ERCC1 | c.660G>A p.A220= | Silent (SNP) | VAF 111/454 reads (24%) | catalogued as rs753209831, COSV99185244; called by muse, mutect2, varscan2
- FNDC7 | c.1917G>T p.L639= | Silent (SNP) | VAF 109/525 reads (21%) | called by muse, mutect2, varscan2
- GMNC | c.393C>T p.L131= | Silent (SNP) | VAF 103/419 reads (25%) | called by muse, mutect2, varscan2
- HSD3B7 | c.558G>A p.T186= | Silent (SNP) | VAF 182/410 reads (44%) | catalogued as rs760192112, COSV52679734; ClinVar: uncertain significance; called by muse, varscan2
- KCNQ3 | c.1311T>C p.G437= | Silent (SNP) | VAF 169/1197 reads (14%) | called by muse, mutect2, varscan2
- KLHL2 | c.1494G>A p.L498= | Silent (SNP) | VAF 51/285 reads (18%) | catalogued as rs770642847; called by muse, mutect2, varscan2
- LYSMD1 | c.90G>T p.S30= | Silent (SNP) | VAF 112/436 reads (26%) | called by muse, mutect2, varscan2
- MFSD3 | c.1182C>A p.L394= | Silent (SNP) | VAF 127/914 reads (14%) | catalogued as COSV56742378; called by muse, mutect2, varscan2
- MIEF2 | c.402C>T p.F134= | Silent (SNP) | VAF 180/412 reads (44%) | catalogued as rs544114638, COSV58943956; called by muse, mutect2, varscan2
- MYL3 | c.412C>A p.R138= | Silent (SNP) | VAF 161/641 reads (25%) | catalogued as COSV52767826; called by muse, mutect2, varscan2
- OR1L8 | c.354C>G p.V118= | Silent (SNP) | VAF 124/321 reads (39%) | called by muse, mutect2, varscan2
- RANBP2 | c.8271T>C p.L2757= | Silent (SNP) | VAF 73/301 reads (24%) | called by muse, mutect2, varscan2
- TEP1 | c.2115A>G p.A705= | Silent (SNP) | VAF 110/395 reads (28%) | called by muse, mutect2, varscan2
- AGGF1 | c.-42C>G | 5'UTR (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- BBS2 | c.1527+71G>C | Intron (SNP) | VAF 22/95 reads (23%) | called by muse, varscan2
- CD37 | c.-93C>G | 5'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- DLL3 | c.1093+41del | Intron (DEL) | VAF 69/325 reads (21%) | called by mutect2, pindel, varscan2
- DPY19L2 | c.1581-60T>A | Intron (SNP) | VAF 37/133 reads (28%) | catalogued as COSV100192982; called by muse, mutect2, varscan2
- EIF1B | c.*64C>A | 3'UTR (SNP) | VAF 90/325 reads (28%) | called by muse, mutect2, varscan2
- FCGR2A | c.*14G>T | 3'UTR (SNP) | VAF 79/591 reads (13%) | catalogued as COSV99615089; called by muse, varscan2
- IFIT5 | c.*64T>A | 3'UTR (SNP) | VAF 30/86 reads (35%) | catalogued as rs1209147359; called by muse, mutect2, varscan2
- MYRF | c.2014-9C>T | Intron (SNP) | VAF 173/837 reads (21%) | called by muse, mutect2, varscan2
- NALCN | c.2193-5725G>A | Intron (SNP) | VAF 82/229 reads (36%) | called by muse, mutect2, varscan2
- NKAIN3 | c.472-54388C>A | Intron (SNP) | VAF 49/322 reads (15%) | called by muse, mutect2, varscan2
- PAX3 | c.586+157C>G | Intron (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- SCFD2 | c.1562-37113C>T | Intron (SNP) | VAF 19/63 reads (30%) | catalogued as rs1051079945; called by muse, mutect2, varscan2
- SCG2 | c.*87T>C | 3'UTR (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- SIRT6 | c.534-32C>T | Intron (SNP) | VAF 89/311 reads (29%) | catalogued as rs1463898152; called by muse, mutect2, varscan2
- THOC1 | c.1086+82A>G | Intron (SNP) | VAF 67/170 reads (39%) | called by muse, mutect2, varscan2
- UPF1 | c.3052+53T>G | Intron (SNP) | VAF 142/487 reads (29%) | called by muse, mutect2, varscan2
